Gene-level copy-number profile of tumor specimen TCGA-FB-A545-01A from TCGA case TCGA-FB-A545, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 72.9 years (26,635 days).
Specimen TCGA-FB-A545-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.9826d13d-ca8d-4327-b5bf-776ca49ca30e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FB-A545-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30d70ce0-05bc-4628-ac74-f6f371a61545

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 398; copy number 1: 16,906; copy number 2: 41,244; copy number 3: 1,168; copy number 4: 9; copy number 5: 23; copy number 6: 50; copy number 8: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FB-A545-01A-11D-A26H-01): tumor purity 0.52, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 398 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:37,575,587–52,777,345, 398 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 85 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:18,225,635–18,389,647, 12 genes, copy number 8 (within-gene range 3–8): LLGL1, FLII, MIEF2, AC127537.1, TOP3A, RPL7AP65, RPL21P121, SMCR8, SHMT1, MIR6778, EVPLL, AL353997.2.
- chr17:19,383,442–20,403,557, 50 genes, copy number 6 (within-gene range 2–6): MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1, AKAP10, AC005730.3, AC005730.2, SPECC1, AC005730.1, KCTD9P1, RNU6-258P, AC004702.1, RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2.
- chr17:21,214,322–21,783,465, 23 genes, copy number 5: AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1.

Autosomal genes at a single copy (total copy number 1): 14,485. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
